Somatic mutation profile of tumor specimen 0DVJOU from CCDI case PBCMLN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.4 years (155 days).
Specimen 0DVJOU: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28a8d540-327b-4726-9567-763e52f7693a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76f79e24-320c-4143-85e8-0e925d24d858

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 28/500 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MCHR2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 126/416 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs753571792; called by muse, varscan2
- ADGRG3 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG2 | c.3074G>A p.C1025Y | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MMD2 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2
- CTR9 | c.1566C>T p.N522= | Silent (SNP) | VAF 98/251 reads (39%) | called by muse, mutect2, varscan2
